Surgical pathology report (de-identified scan), TCGA case TCGA-19-1392, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-1392-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS

A. AND B. BRAIN TUMOR, C. TUMOR CORE AND D. TUMOR EDGE, BIOPSY AND REMOVAL:
--GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

E. NORMAL APPEARING BRAIN, RULE OUT INFILTRATION, BIOPSY:
--BRAIN TISSUE INFILTRATED BY SCANT SMALL ATYPICAL KI-67 POSITIVE CELLS, SEE NOTE.

Note: The findings are consistent with infiltration by a minimal amount of malignant glioma. Immunohistochemistry for Ki-67 labels approximately 2-3% of cells in the areas evaluated.

One or more of the reagents used to perform assays on this specimen MAY have contained components considered to be analyte specific reagents (ASR's). ASR's have not been cleared or approved by the U.S. Food and Drug Administration. These assays were developed and their performance characteristics determined by the Department of Pathology at [REDACTED]. The assays were performed with appropriate positive and negative controls.

Electronically Signed Out By By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consult Diagnosis

A: Microscopic and Touch Imprint: Glioblastoma multiforme.

Clinical History:

brain tumor

Specimens Submitted As:

A: BRAIN TUMOR
B: PERMANENT
C: TUMOR CORE
D: TUMOR EDGE BRAI
E: NORMAL APPEARING BRAIN R/O INFILTRATION

Gross Description:

A: Received fresh for intraoperative consultation, labelled with the patient's name and hospital number, and "brain tumor", is a 1 x 1 x 0.4 cm aggregate of white-tan, soft tissue fragments. The specimen is submitted for touch imprint, permanent section and frozen section.

B: Received in formalin labeled with the patient's name and number, and "B-permanent, 3", are multiple irregular, pink-tan, soft, cerebriform tissue fragments admixed with blood clots measuring in aggregate 5.5 x 4.5 x 2.0 cm. With exception to the blood clots, the specimen is submitted entirely in 12 cassettes.

[page 2 of 2]
C:Received in formalin labeled with the patient's name and number, and "C-tumor core, 4", are multiple irregular, pink-tan, soft cerebriform tissue fragments admixed with red brown blood clots measuring in aggregate 6.9 x 6.2 x 2.0 cm. With exception to the blood clots, the specimen is submitted entirely in 11 cassettes.

D:Received in formalin labeled with the patient's name and number and "D-tumor edge, 5", are multiple irregular, pink-tan, soft, cerebriform tissue fragments measuring in aggregate 12.3 x 6.0 x 2.0 cm. Submitted entirely in 31 cassettes.

E:Received in formalin labeled with the patient's name and number, and "E-normal appearing brain, 6", are multiple irregular, pink-tan, soft, cerebriform tissue fragments measuring in aggregate 4.0 x 2.8 x 1.4 cm. Submitted entirely in five cassettes.

Source: NCI Genomic Data Commons file f6141db9-89b2-400f-afe2-c5b395c2f848 (TCGA-19-1392.86AED977-CD39-47B0-94BF-99FCDBC8AC48.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).